Somatic mutation profile of tumor specimen TCGA-EL-A3MZ-01A (aliquot TCGA-EL-A3MZ-01A-11D-A21A-08) from TCGA case TCGA-EL-A3MZ, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage III; Age at diagnosis: 66.3 years (24,208 days).
Specimen TCGA-EL-A3MZ-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) c89f1d48-7de0-4964-817f-f32947dbf253.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-EL-A3MZ-11A (Solid Tissue Normal), aliquot TCGA-EL-A3MZ-11A-11D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/5afaa20f-785b-480d-b37d-f3be84a77357

The open-access MAF lists 26 somatic variants for this specimen: 22 protein-altering or splice-affecting, 4 silent.
By variant classification: Missense Mutation 17, Silent 4, Nonsense Mutation 2, In Frame Del 1, Frame Shift Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 47/121 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- ACVR2B | c.1075G>C p.V359L | Missense Mutation (SNP) | VAF 31/111 reads (28%) | SIFT deleterious (0.02); PolyPhen benign (0.379); catalogued as COSV61701200; called by muse, mutect2, varscan2
- C7orf33 | c.49C>A p.L17I | Missense Mutation (SNP) | VAF 26/106 reads (25%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.281); catalogued as COSV61022719; called by muse, mutect2, varscan2
- IGF2R | c.1597G>A p.E533K | Missense Mutation (SNP) | VAF 71/231 reads (31%) | SIFT tolerated (0.41); PolyPhen benign (0.02); catalogued as rs778725774, COSV63626464; called by muse, mutect2, varscan2
- NFAT5 | c.4128A>T p.L1376F | Missense Mutation (SNP) | VAF 36/107 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.055); catalogued as COSV63025236; called by muse, mutect2, varscan2
- PALMD | c.524C>T p.A175V | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.815); catalogued as rs1440537866, COSV54162934; called by muse, mutect2, varscan2
- PHOX2A | c.733G>A p.A245T | Missense Mutation (SNP) | VAF 4/15 reads (27%) | SIFT tolerated, low confidence (0.76); PolyPhen benign (0.003); catalogued as COSV53353359; called by muse, mutect2
- PIAS3 | c.404A>G p.Y135C | Missense Mutation (SNP) | VAF 29/329 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs781818284, COSV65170996; called by muse, mutect2
- PPP2R1A | c.818C>T p.A273V | Missense Mutation (SNP) | VAF 39/129 reads (30%) | SIFT tolerated (0.1); PolyPhen benign (0.018); catalogued as COSV59042465; called by muse, mutect2, varscan2
- PTCD1 | c.22C>T p.R8* | Nonsense Mutation (SNP) | VAF 24/172 reads (14%) | catalogued as rs138103080; called by muse, mutect2, varscan2
- RBM12B | c.1055C>T p.P352L | Missense Mutation (SNP) | VAF 19/66 reads (29%) | SIFT tolerated (0.66); PolyPhen possibly damaging (0.76); catalogued as COSV66968000; called by muse, mutect2, varscan2
- RERGL | c.227G>A p.W76* | Nonsense Mutation (SNP) | VAF 61/170 reads (36%) | catalogued as COSV57460958; called by muse, mutect2, varscan2
- SEMA7A | c.1828C>T p.H610Y | Missense Mutation (SNP) | VAF 31/83 reads (37%) | SIFT tolerated (0.16); PolyPhen benign (0.39); catalogued as COSV56089329; called by muse, mutect2, varscan2
- SYNGR4 | c.82G>T p.V28F | Missense Mutation (SNP) | VAF 46/103 reads (45%) | SIFT tolerated (0.06); PolyPhen benign (0.099); catalogued as COSV53155216; called by muse, mutect2, varscan2
- TERT | c.1409G>A p.R470H | Missense Mutation (SNP) | VAF 6/14 reads (43%) | SIFT tolerated (0.39); PolyPhen benign (0.007); catalogued as rs1013341756, COSV57199527; called by muse, mutect2, varscan2
- THSD1 | c.802G>A p.V268I | Missense Mutation (SNP) | VAF 34/129 reads (26%) | SIFT tolerated (0.5); PolyPhen benign (0.003); catalogued as rs201109452; called by muse, mutect2, varscan2
- UQCRC1 | c.1178A>T p.N393I | Missense Mutation (SNP) | VAF 43/112 reads (38%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52550899; called by muse, mutect2, varscan2
- YTHDC1 | c.1066A>G p.R356G (on ENST00000344157 / NM_001031732.4; = p.R338G on NM_133370.4) | Missense Mutation (SNP) | VAF 24/118 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV60008713; called by muse, mutect2, varscan2
- AP3M2 | c.318_330del p.V107Rfs*24 | Frame Shift Del (DEL) | VAF 47/213 reads (22%) | called by mutect2, pindel, varscan2
- MTMR12 | c.1097_1099del p.I366del | In Frame Del (DEL) | VAF 18/99 reads (18%) | called by mutect2, pindel, varscan2
- SRP68 | c.644+2_644+3insTT | Splice Region (INS) | VAF 16/59 reads (27%) | called by mutect2, pindel, varscan2
- ZNF658 | c.2315G>T p.C772F | Missense Mutation (SNP) | VAF 7/16 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- AFF3 | c.471C>T p.D157= | Silent (SNP) | VAF 47/128 reads (37%) | catalogued as rs781371392, COSV57840898; called by muse, mutect2, varscan2
- NLRC3 | c.897G>A p.E299= | Silent (SNP) | VAF 7/100 reads (7%) | catalogued as rs1231659054, COSV57087334; called by muse, mutect2
- SBNO1 | c.2634C>T p.I878= (on ENST00000420886; = p.I877= on NM_018183.5) | Silent (SNP) | VAF 40/158 reads (25%) | catalogued as rs567091125, COSV57339019; called by muse, mutect2, varscan2
- SLC22A14 | c.1440G>T p.T480= | Silent (SNP) | VAF 83/235 reads (35%) | catalogued as COSV56196665, COSV56199259; called by muse, mutect2, varscan2
